National Lung Screening Trial (NLST) participant 100353 — screening results, CT findings and lung cancer
Open-access record from the public subset of National Lung Screening Trial clinical data distributed by the NCI Imaging Data Commons (release v24, collection nlst). NLST enrolled current and former heavy smokers aged 55–74 in 2002–2004 and randomised them to three annual screens (T0, T1, T2) with low-dose CT or chest radiography, with follow-up through 2009. Coded values are written out from the NLST data dictionaries; day counts are days from randomisation.
https://doi.org/10.7937/TCIA.HMQ8-J677

Participant
Age at randomisation: 73 years; Gender: male; Race: White; Cigarette smoking status at randomisation: current smoker; Enrolled through a Lung Screening Study (LSS) centre (from the participant ID range).

Screening results (official result of each annual screen after comparison with prior images; this participant has CT screening exam records, so these are low-dose CT screens)
- T0 (day 16): Positive, change unspecified: nodule(s) >= 4 mm or enlarging nodule(s), mass(es), or other non-specific abnormalities suspicious for lung cancer. Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 120 mA, display field of view 33 cm, reconstruction filter Siemens B30.
- T1 (day 345): Positive, no significant change: stable abnormalities potentially related to lung cancer, unchanged since the prior screening exam. Isolation read, before comparison with prior images: positive (nodule(s) >= 4 mm, mass or other suspicious abnormality). Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 80 mA, 32 effective mAs, display field of view 37 cm, reconstruction filter Siemens B30.
- T2 (day 730): Positive, other. Isolation read, before comparison with prior images: positive (nodule(s) >= 4 mm, mass or other suspicious abnormality). Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 80 mA, 32 effective mAs, display field of view 36 cm, reconstruction filter Siemens B30.

Abnormalities recorded by the reading radiologist on the CT screens (7 abnormalities; numbered within each screening year; size, margins, attenuation and location were collected only for non-calcified nodules or masses of at least 4 mm; interval-change items come from the comparison read)
- T0 abnormality 1: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the left upper lobe; longest diameter 5 mm, longest perpendicular diameter 4 mm; margins poorly defined; predominant attenuation ground glass; greatest diameter on CT slice 19.
- T1 abnormality 1: Other minor abnormality noted.
- T1 abnormality 2: Other minor abnormality noted.
- T1 abnormality 3: Emphysema.
- T1 abnormality 4: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the left upper lobe; longest diameter 5 mm, longest perpendicular diameter 5 mm; margins poorly defined; predominant attenuation ground glass; greatest diameter on CT slice 19; pre-existing on earlier images (earliest visible day 16); no interval growth; no suspicious change in attenuation.
- T1 abnormality 5: Benign lung nodule(s) (benign calcification).
- T2 abnormality 1: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the left upper lobe; longest diameter 8 mm, longest perpendicular diameter 8 mm; margins poorly defined; predominant attenuation ground glass; greatest diameter on CT slice 20; pre-existing on earlier images (earliest visible day 16); interval growth; no suspicious change in attenuation.

Lung cancer (2 primary lung cancer records; the first confirmed lung cancer occurred after the screening years; study year of the first confirmed lung cancer: T5; the diagnosis is not linked to a positive screen by the trial's diagnostic-procedure linking algorithm)
1. First primary lung cancer, diagnosed day 1,954, study year T5. Site: upper lobe of lung (ICD-O-3 C34.1), determined from histology. Primary tumour location: left upper lobe. Histology: bronchiolo-alveolar adenocarcinoma, NOS (ICD-O-3 8250/3). Grade: well differentiated (G1). Tumour size on pathology: 19 mm. AJCC 6th edition staging: stage IA (best stage, from clinical TNM); clinical T1 N0 M0 (stage IA); a stage recorded on the form without separate T, N, M: stage IV. AJCC 7th edition staging: stage IA; clinical T1a N0 M0. Summary stage: distant.
2. Subsequent primary lung cancer, diagnosed day 1,963, study year T5. Site: upper lobe of lung (ICD-O-3 C34.1), determined from histology. Histology: squamous cell carcinoma, NOS (ICD-O-3 8070/3). Cancer type as recorded on the NLST diagnostic evaluation form (the trial's best information on type): squamous cell carcinoma, large cell, nonkeratinizing, NOS (ICD-O-3 8072). Grade: poorly differentiated (G3). Tumour size on pathology: 15 mm. AJCC 6th edition staging: stage IIA (best stage, from pathologic TNM); clinical T1 N0 M0 (stage IA); pathologic T1 N1 M0 (stage IIA). AJCC 7th edition staging: stage IIA; clinical T1a N0 M0; pathologic T1a N1 M0.

Follow-up
Last known free of lung cancer: day 1,802.
